Gene-level copy-number profile of tumor specimen HTMCP-03-06-02346-01A from CGCI case HTMCP-03-06-02346, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02346-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 14b5b81b-42d1-48bc-81fa-4cf0d2bd6c37.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02346-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/e09ca460-9df2-4270-9d52-0d732ff87af9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 5; copy number 2: 6,106; copy number 3: 13,205; copy number 4: 31,330; copy number 5: 3,908; copy number 6: 2,909; copy number 7: 888; copy number 9: 9; copy number 10: 16; copy number 12: 3.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,157,443, 4 genes: AC116562.1, OR7E103P, UNC93B4, OR7E99P.
- chr16:90,173,217–90,222,851, 2 genes (within-gene range 0–2): LINC02193, CICP25.
- chr19:1,177,558–1,228,431, 2 genes (within-gene range 0–2): STK11, HMGB2P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,094,987–31,434,680, 9 genes, copy number 9: SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2, ZCCHC17, AL451070.1, FABP3, SERINC2.
- chr7:38,239,580–38,249,572, 1 gene, copy number 10: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 10: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr19:43,192,702–43,269,530, 3 genes, copy number 12: PSG4, CEACAMP10, PSG9.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
